Somatic mutation profile of tumor specimen TCGA-EJ-A65G-01A (aliquot TCGA-EJ-A65G-01A-21D-A29Q-08) from TCGA case TCGA-EJ-A65G, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.0 years (20,821 days).
Specimen TCGA-EJ-A65G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1411a0e0-efc6-41b5-8835-8d72a16ce5c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65G-10A (Blood Derived Normal), aliquot TCGA-EJ-A65G-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f26000ef-459b-499c-aa75-c38770280837

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1909_1912del p.S637Tfs*53 | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | catalogued as rs398122969; ClinVar: pathogenic; called by mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 11/137 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2
- ADGRB3 | c.1052G>T p.W351L | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV65384968; called by muse, mutect2, varscan2
- BARHL2 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV100966045; called by mutect2, varscan2
- CTC1 | c.515A>G p.N172S | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs767490808, COSV59852648; called by muse, mutect2, varscan2
- CUTC | c.327T>A p.Y109* | Nonsense Mutation (SNP) | VAF 9/171 reads (5%) | catalogued as COSV65081649; called by muse, mutect2
- LRRIQ3 | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV63042353; called by muse, mutect2, varscan2
- MTF1 | c.924T>A p.S308R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV65988666; called by muse, mutect2, varscan2
- MTF1 | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV65988670; called by muse, mutect2, varscan2
- OR5M10 | c.758del p.G253Efs*8 | Frame Shift Del (DEL) | VAF 43/214 reads (20%) | catalogued as COSV101595898; called by mutect2, varscan2
- OR8K3 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV57131053; called by muse, mutect2, varscan2
- PHF24 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1188563317, COSV54273085; called by muse, mutect2, varscan2
- PLEKHN1 | c.1605G>T p.M535I (on ENST00000379409; = p.M483I on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58021505; called by muse, mutect2, varscan2
- PRRT3 | c.1562T>C p.M521T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1003210002, COSV55976723; called by muse, mutect2, varscan2
- RTKN | c.258_273delinsC p.M86_R91delinsI (on ENST00000272430 / NM_001015055.2; = p.M73_R78delinsI on NM_033046.2) | In Frame Del (DEL) | VAF 40/187 reads (21%) | called by pindel, varscan2*
- KCTD10 | c.600C>G p.V200= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV57326352; called by muse, mutect2, varscan2
- PAN3 | c.915C>T p.N305= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as rs766122141, COSV66707969; called by muse, mutect2, varscan2
- POLQ | c.3390T>C p.N1130= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs779774025, COSV51748634; called by muse, mutect2, varscan2
